Somatic mutation profile of tumor specimen 0DLX5A from CCDI case PBBZYA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 18.0 years (6,580 days).
Specimen 0DLX5A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a56951c-e33c-4389-b09a-7a9a37ee0cec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLX4Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a58471a0-7027-469c-a3de-c539d3564034

The open-access MAF lists 18 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Intron 3, 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1G2 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 129/702 reads (18%) | catalogued as rs138038447; called by muse, mutect2, varscan2
- APOB | c.4537C>T p.R1513W | Missense Mutation (SNP) | VAF 218/1111 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs139621265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL26A1 | c.812C>T p.P271L (on ENST00000313669 / NM_001278563.3; = p.P269L on NM_133457.4) | Missense Mutation (SNP) | VAF 394/1388 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as rs766773360; called by muse, mutect2, varscan2
- DNAH5 | c.8726G>A p.R2909H | Missense Mutation (SNP) | VAF 590/1401 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs756069405, COSV54231201, COSV54255638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 285/1707 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1554532927, COSV57032667; called by muse, mutect2, varscan2
- HHIPL1 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 64/815 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs750734841; called by muse, mutect2
- SERPINA9 | c.528C>G p.N176K | Missense Mutation (SNP) | VAF 490/1124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPON1 | c.825G>T p.Q275H | Missense Mutation (SNP) | VAF 501/923 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CAPNS2 | c.180G>A p.P60= | Silent (SNP) | VAF 264/998 reads (26%) | catalogued as rs745662780; called by muse, mutect2, varscan2
- NLRP2 | c.96C>T p.T32= | Silent (SNP) | VAF 521/1156 reads (45%) | catalogued as rs776117162; called by muse, mutect2, varscan2
- OR4K3 | c.936C>A p.I312= | Silent (SNP) | VAF 283/675 reads (42%) | called by muse, mutect2, varscan2
- RUFY4 | c.1140C>T p.H380= | Silent (SNP) | VAF 104/1198 reads (9%) | catalogued as rs575133624, COSV60245904; called by muse, mutect2
- ST14 | c.975C>T p.P325= | Silent (SNP) | VAF 494/1801 reads (27%) | catalogued as rs367648163; called by muse, varscan2
- IRF8 | c.*48C>G | 3'UTR (SNP) | VAF 181/601 reads (30%) | called by muse, mutect2, varscan2
- MYO9B | c.2374-11G>A | Intron (SNP) | VAF 115/558 reads (21%) | catalogued as rs1441478677; called by muse, mutect2, varscan2
- SLC13A2 | c.1097+82G>T | Intron (SNP) | VAF 86/357 reads (24%) | called by muse, mutect2, varscan2
- TRIM37 | c.*88T>A | 3'UTR (SNP) | VAF 100/327 reads (31%) | called by muse, mutect2, varscan2
- YAF2 | c.152+26951G>T | Intron (SNP) | VAF 34/1152 reads (3%) | catalogued as rs1041371904, COSV100586253; called by muse, mutect2
